Somatic mutation profile of tumor specimen 0DWNTO from CCDI case PBCPGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.4 years (155 days).
Specimen 0DWNTO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d9b3c24-96bb-4334-999e-cc5f1d5b0ded.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38da8fa2-21f9-49dd-b986-525b94b1a170

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH13 | c.4645G>A p.E1549K | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831365; called by muse, varscan2
- HMX1 | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR4C13 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); called by muse, varscan2
- CRYM | c.402C>A p.P134= | Silent (SNP) | VAF 77/479 reads (16%) | called by muse, varscan2
